Somatic mutation profile of tumor specimen C3N-02084-01 (aliquot CPT0109950007) from CPTAC case C3N-02084, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.6 years (19,205 days).
Specimen C3N-02084-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e64092c9-68e8-4e03-b421-951ae0626b45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02084-71 (Blood Derived Normal), aliquot CPT0146300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f8e866c-654d-4a29-9d1a-33d325331c06

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Nonsense Mutation 6, Frame Shift Del 3, Intron 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.397del p.T133Lfs*26 | Frame Shift Del (DEL) | VAF 112/297 reads (38%) | catalogued as rs1559428134, CM994242, COSV56562793; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL4A4 | c.3452G>T p.G1151V | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM151516; called by muse, mutect2, varscan2
- COL5A1 | c.3014C>A p.T1005K | Missense Mutation (SNP) | VAF 92/386 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV65668393; called by muse, mutect2, varscan2
- CYP51A1 | c.934A>T p.I312F | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1397040817; called by muse, mutect2, varscan2
- DCHS1 | c.7900C>G p.H2634D | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.241); catalogued as COSV54997059; called by muse, mutect2, varscan2
- DIAPH1 | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463095601; called by muse, mutect2
- GPCPD1 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV66830506; called by muse, mutect2, varscan2
- IVL | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as rs760459838; called by muse, mutect2, varscan2
- MAGI3 | c.1168C>G p.P390A | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100290469; called by muse, mutect2, varscan2
- PCNX1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.978); catalogued as rs1037443498, COSV53095100; called by muse, mutect2
- PDZD8 | c.2513A>T p.E838V | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53693435; called by muse, mutect2, varscan2
- PRR11 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs781296642; called by muse, varscan2
- UQCRFS1 | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs985046690; called by muse, mutect2, varscan2
- ACO1 | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- AKAP11 | c.5238A>T p.Q1746H | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- AUTS2 | c.914C>G p.P305R | Missense Mutation (SNP) | VAF 115/432 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- C4BPB | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 48/198 reads (24%) | called by muse, mutect2, varscan2
- CEP290 | c.4295_4302+1del p.X1432_splice | Splice Site (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel
- CPSF1 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DENND2A | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 31/381 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FMR1NB | c.329del p.N110Mfs*17 | Frame Shift Del (DEL) | VAF 53/122 reads (43%) | called by mutect2, pindel, varscan2
- GTF2I | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by mutect2, varscan2
- HORMAD1 | c.103G>C p.A35P | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTU | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); called by mutect2, varscan2
- KCNJ14 | c.65del p.G22Afs*43 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- KRT38 | c.1300C>A p.R434S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OBSCN | c.7930G>A p.V2644M | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- PRPF39 | c.476T>A p.I159K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PSMF1 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTBP3 | c.1577T>A p.I526N | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RBM26 | c.740C>G p.P247R | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ROS1 | c.2931G>A p.W977* | Nonsense Mutation (SNP) | VAF 33/170 reads (19%) | called by muse, mutect2, varscan2
- SCEL | c.215T>A p.L72* | Nonsense Mutation (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- SEC16B | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- SLFN11 | c.1343A>C p.D448A | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SOX11 | c.616A>T p.S206C | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31D4 | c.2311G>T p.G771* | Nonsense Mutation (SNP) | VAF 114/680 reads (17%) | called by muse, mutect2, varscan2
- TPP2 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TRIM25 | c.635A>T p.Q212L | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRIM47 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- UBE4A | c.408G>C p.Q136H | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- UNC13A | c.3368T>A p.L1123H | Missense Mutation (SNP) | VAF 78/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- XIRP1 | c.4958A>C p.Y1653S | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF749 | c.827A>T p.E276V | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- CAMSAP1 | c.546G>A p.P182= | Silent (SNP) | VAF 69/227 reads (30%) | catalogued as rs1050116539; called by muse, mutect2, varscan2
- DISP2 | c.658C>T p.L220= | Silent (SNP) | VAF 47/241 reads (20%) | called by muse, mutect2, varscan2
- GRIN2D | c.3036C>A p.R1012= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs1482308444; called by muse, mutect2, varscan2
- LY75-CD302 | c.5277A>G p.Q1759= | Silent (SNP) | VAF 37/171 reads (22%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.1239A>G p.E413= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as rs201105272; called by muse, mutect2, varscan2
- PLCG2 | c.1288T>C p.L430= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- RABGAP1L | c.460C>T p.L154= (on ENST00000489615 / NM_001243765.2; = p.L37= on NM_001243764.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/210 reads (25%) | called by muse, mutect2, varscan2
- SLC35G1 | c.711G>A p.S237= (on ENST00000427197 / NM_001134658.3; = p.S236= on NM_153226.4) | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs1391573295, COSV101004123, COSV65055638; called by muse, mutect2, varscan2
- SLC6A6 | c.1464T>C p.L488= | Silent (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- TBCE | c.504G>A p.L168= (on ENST00000366601; = p.L231= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/374 reads (24%) | catalogued as rs747470605; called by muse, mutect2, varscan2
- VSX2 | c.1032T>C p.D344= | Silent (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2, varscan2
- FAM78A | c.323+5534A>T | Intron (SNP) | VAF 88/312 reads (28%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.925C>T | RNA (SNP) | VAF 138/456 reads (30%) | called by muse, varscan2
- SEC14L2 | c.55-876G>A | Intron (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
